Somatic mutation profile of tumor specimen TCGA-HT-7474-01A (aliquot TCGA-HT-7474-01A-11D-2024-08) from TCGA case TCGA-HT-7474, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 52.4 years (19,149 days).
Specimen TCGA-HT-7474-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b59b59f-f3b3-4aca-8cae-240eafc109ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7474-10A (Blood Derived Normal), aliquot TCGA-HT-7474-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5942cf6-f432-4edc-9afc-4878722d2384

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 11, Silent 7, Translation Start Site 1, Frame Shift Del 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 23/68 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.800G>C p.R267P | Missense Mutation (SNP) | VAF 22/29 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587780075, CM921040, COSV52675189, COSV52691512, COSV52734317, COSV52740807; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACSL6 | c.2T>C p.M1? (on ENST00000379240; = p.M26T on NM_015256.4 and 1 other RefSeq transcript) | Translation Start Site (SNP) | VAF 9/23 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.196); catalogued as COSV57294169; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1678C>A p.L560I | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.944); catalogued as COSV58551647; called by muse, mutect2
- GABRB1 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV54970002; called by muse, mutect2, varscan2
- GLRA4 | c.1090G>T p.D364Y | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV100128996; called by muse, mutect2
- MTERF4 | c.170G>A p.C57Y | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371634170; called by muse, mutect2, varscan2
- PAPPA | c.4661G>C p.C1554S | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60277070; called by muse, mutect2, varscan2
- SMPD3 | c.1535A>G p.N512S | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54710308; called by muse, mutect2, varscan2
- TAS2R16 | c.52T>C p.S18P | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50796795; called by muse, mutect2, varscan2
- TTN | c.29068A>G p.T9690A (on ENST00000591111; = p.T8763A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/163 reads (13%) | PolyPhen benign (0.124); catalogued as COSV59875046, COSV59922645; called by muse, mutect2, varscan2
- TTN | c.4922C>A p.T1641K (on ENST00000591111; = p.T1595K on NM_003319.4) | Missense Mutation (SNP) | VAF 8/68 reads (12%) | PolyPhen probably damaging (0.997); catalogued as COSV59875064; called by muse, mutect2, varscan2
- ATRX | c.5618dup p.Q1874Pfs*8 | Frame Shift Ins (INS) | VAF 71/159 reads (45%) | called by mutect2, pindel, varscan2
- FSIP1 | c.1330_1337del p.L444Vfs*5 | Frame Shift Del (DEL) | VAF 24/109 reads (22%) | called by mutect2, pindel, varscan2
- TLR7 | c.3011_3019del p.R1004_R1006del | In Frame Del (DEL) | VAF 48/108 reads (44%) | called by mutect2, pindel, varscan2
- GK2 | c.1536T>C p.G512= | Silent (SNP) | VAF 29/109 reads (27%) | catalogued as COSV62625993; called by muse, mutect2, varscan2
- INPP5A | c.501C>A p.I167= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV61246418; called by muse, mutect2, varscan2
- NINL | c.3948G>A p.L1316= | Silent (SNP) | VAF 59/205 reads (29%) | catalogued as COSV53998303; called by muse, varscan2
- NINL | c.3864G>A p.L1288= | Silent (SNP) | VAF 76/304 reads (25%) | catalogued as rs1298248030, COSV53998310; called by muse, varscan2
- SSB | c.820C>T p.L274= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as COSV53625803; called by muse, mutect2, varscan2
- STAB1 | c.1713G>A p.Q571= | Silent (SNP) | VAF 4/72 reads (6%) | catalogued as rs1272848218; called by muse, mutect2
- ZPBP | c.1014A>G p.Q338= | Silent (SNP) | VAF 39/128 reads (30%) | catalogued as rs138428432; called by muse, mutect2, varscan2
